Surgical pathology report (de-identified scan), TCGA case TCGA-A4-8516, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-8516-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Component Results

Final Report

DIAGNOSIS

RIGHT KIDNEY MASS, PARTIAL NEPHRECTOMY:

1. Renal cell carcinoma, papillary type 1, 3.6 cm
2. Tumor focally extends into perinephric adipose tissue
3. Surgical margins are negative for tumor
4. Negative for lymphatic/vascular invasion by tumor
5. Renal cell carcinoma, clear cell type, Furhman grade 2 of 4, 0.1 cm, incidental finding confined to the kidney
6. Residual renal parenchyma with papillary adenomas, less then 0.5 cm
7. See comment
8. Please see kidney cancer staging parameters below

COMMENT

The presence of a papillary type 1 renal cell carcinoma along with multiple papillary adenomas in the patient's kidney raises the possibility of a hereditary papillary renal cell carcinoma (HPRC) syndrome. In HPRC patients, the kidneys demonstrate multiple bilateral renal cell carcinomas, most with low grade nuclear features. HPRC is caused by germline mutations in the c-met oncogene, and demonstrates autosomal dominant inheritance. Further studies and possible genetic counseling could be considered if this patient is felt to be clinically at risk for this syndrome. Please call [REDACTED]

References:

MACROSCOPIC
PROCEDURE
Partial nephrectomy

[page 2 of 3]
SPECIMEN LATERALITY

Right

TUMOR SITE

Upper pole

TUMOR SIZE

3.6 cm

TUMOR FOCALITY

Unifocal

MACROSCOPIC EXTENT OF TUMOR

Tumor limited to kidney

MICROSCOPIC

HISTOLOGIC TYPE

Papillary renal cell carcinoma

TUMOR NECROSIS

Not identified

HISTOLOGICAL GRADE

G2: Nuclei slightly irregular, approximately 15 um; nucleoli evident

MICROSCOPIC EXTENT OF TUMOR

Tumor extension into perinephric tissue (beyond renal capsule)

LYMPHATIC VASCULAR INVASION

Not identified

MARGINS

Uninvolved by carcinoma

NON-NEOPLASTIC KIDNEY PATHOLOGY

papillary adenomas

PATHOLOGIC STAGING

EXTENT OF INVASION

pT3a. (Tumor grossly extends into the renal vein or its segmental (muscle containing) branches, or tumor invades perirenal and/or renal sinus fat but not beyond Gerota's fascia)

REGIONAL LYMPH NODES

pNX. (Regional lymph nodes cannot be assessed)

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT3aNXM0

Stage: III

* The pathologic stage presumes no lymph node metastasis.

** The pathologic stage presumes no distant metastasis.

Attending Pathologist:

CLINICAL INFORMATION

Right kidney mass, clip on margin

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Kidney, partial, right kidney mass
Labeled "Rt kidney mass clip on margin" is a 24.1 gram, 5 x 3.5 x 3 cm portion of kidney with attached perinephric fat. The attached perinephric fat has a thickness of 2.7 cm. The parenchymal margin is indicated by an attached silver surgical clip. The parenchymal margin is inked black. The nonparenchymal surface with surrounding perinephric fat and possible intact Gerota's fascia is inked blue. The tissue is serially sectioned revealing a 3.6 x 2.8 x 2 cm red-yellow soft to friable focally hemorrhagic mass. The mass appears to abut the blue inked surface and also appears to extend to within 0.1-0.2 cm of the black inked parenchymal margin. The uninvolved

[page 3 of 3]
[REDACTED]

kidney parenchyma is maroon-tan and soft to rubbery.

Representative tissue including closest extension to apparent black inked parenchymal margin is submitted for frozen section diagnosis on one block.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Margins free by 1-2 mm." is rendered by [REDACTED]

Representative tissue is frozen for possible future studies per tumor banking protocol per [REDACTED]

- Summary of sections:
- 1. Frozen section
- 2-12. Central portion of tissue focally with relation to black inked parenchymal margin and with relation to blue inked surface of surrounding perinephric fat and possible Gerota's fascia (tissue in cassettes 7-11 represents tissue adjacent to frozen section tissue)

This case is accessioned in [REDACTED]

Gross dictation by [REDACTED]

MICROSCOPIC
The microscopic appearance substantiates the diagnosis [REDACTED]

[REDACTED]

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL	[REDACTED]	Lab and Collection
Information	[REDACTED]	

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL	[REDACTED]	Result History
Report	[REDACTED]	

Lab Status
Order Complete [3]

[REDACTED] on [REDACTED]

Result Information

Result Date and Time	Status	Provider Status
[REDACTED]	Final result	Reviewed

Lab Information

[REDACTED]

Order Details

Parent Order ID	Child Order ID
-----------------	----------------

[REDACTED]

Source: NCI Genomic Data Commons file 33b09fe8-75b3-49d1-be09-6f5c63dbcf09 (TCGA-A4-8516.0108A584-FFF4-41A2-90A3-182D91B68C5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).